FM case AD5982 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/29b22066-094e-409c-a81e-99bdfbec4202

Male, 60.6 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3); specimen biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
